Somatic mutation profile of tumor specimen TCGA-AX-A1CC-01A (aliquot TCGA-AX-A1CC-01A-11D-A135-09) from TCGA case TCGA-AX-A1CC, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IC; Tumor grade: G3; Age at diagnosis: 65.1 years (23,795 days).
Specimen TCGA-AX-A1CC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 83b34550-11fa-4983-b381-569a14e9d2d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A1CC-10A (Blood Derived Normal), aliquot TCGA-AX-A1CC-10A-01D-A135-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf6e37df-7c35-43e2-b83a-33fdeff94902

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 4, Frame Shift Del 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1126G>A p.G376R (on ENST00000521381 / NM_181523.3; = p.G106R on NM_181504.4) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519757, COSV57123316, COSV57132021, COSV57133701; ClinVar: likely pathogenic; called by mutect2, varscan2
- PPP2R1A | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 14/48 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59042523, COSV59042723; called by mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 7/74 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- ARHGAP35 | c.3359G>A p.R1120Q | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV101351023, COSV101351779; called by muse, mutect2
- CARD16 | c.134G>T p.R45L | Missense Mutation (SNP) | VAF 19/214 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.055); catalogued as COSV100995120; called by muse, mutect2
- CDH26 | c.2056C>T p.L686F (on ENST00000348616 / NM_177980.4; = p.L19F on NM_021810.6) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.178); catalogued as COSV99723044; called by mutect2, varscan2
- DNAH5 | c.7934G>T p.G2645V | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99454614; called by muse, mutect2, varscan2
- GCK | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM074220, COSV100357363; called by muse, mutect2, varscan2
- GPM6B | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs768092899, COSV57423304; called by muse, mutect2, varscan2
- HEATR1 | c.2537G>A p.R846K | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100857806; called by muse, mutect2, varscan2
- KCND1 | c.1273C>G p.R425G | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as COSV99502158; called by muse, mutect2, varscan2
- PLK2 | c.1721A>G p.Y574C | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99956309; called by mutect2, varscan2
- PTPRT | c.2479G>A p.V827I | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.043); catalogued as rs573377632, COSV61976479; called by muse, mutect2, varscan2
- RACGAP1 | c.578G>A p.G193D | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.043); catalogued as COSV100407990; called by muse, mutect2, varscan2
- NCAPH | c.1958_1959del p.S653Tfs*30 | Frame Shift Del (DEL) | VAF 10/103 reads (10%) | called by mutect2, pindel, varscan2
- CHPF2 | c.492G>T p.L164= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV99223372; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1317C>T p.D439= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as rs151261667, COSV62571179; called by muse, mutect2, varscan2
- NAV1 | c.3033C>T p.R1011= | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as COSV55213899, COSV99819779; called by muse, mutect2, varscan2
- NPFFR1 | c.489C>G p.A163= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as rs1226353186, COSV99525023; called by muse, mutect2
- SSPOP | n.9361C>T | RNA (SNP) | VAF 13/63 reads (21%) | catalogued as rs758908839, COSV65139233; called by muse, mutect2, varscan2
- TCF7L2 | c.552+49295C>A | Intron (SNP) | VAF 14/68 reads (21%) | catalogued as COSV100589291; called by muse, mutect2, varscan2
